Somatic mutation profile of tumor specimen TCGA-27-1832-01A (aliquot TCGA-27-1832-01A-01D-1494-08) from TCGA case TCGA-27-1832, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,678 days).
Specimen TCGA-27-1832-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaa58b9b-38b9-485a-b0d5-337c9e4d7083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1832-10A (Blood Derived Normal), aliquot TCGA-27-1832-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eec60af6-0783-4ad2-99f4-8cbc0489871e

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMPRSS6 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387907018, CM093222, COSV60977986, COSV60980115; ClinVar: pathogenic; called by muse, varscan2
- TRPV4 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs267607145, CM100594, COSV55681642; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDR1 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.914); catalogued as rs143948461, COSV65164205; called by muse, mutect2, varscan2
- CEP135 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as rs765207289, COSV57259933, COSV57261354; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944dup p.V982Gfs*4 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs763585044; called by mutect2, pindel, varscan2
- COL5A2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66409657; called by muse, mutect2, varscan2
- CPS1 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1432483864, COSV51809640; called by muse, mutect2, varscan2
- DSEL | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV59491398; called by muse, mutect2, varscan2
- DUS1L | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760210278, COSV60784523; called by muse, mutect2, varscan2
- ENPP7 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs782232450, COSV60386457; called by muse, mutect2, varscan2
- GPR107 | c.598A>G p.N200D | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV61279345; called by muse, mutect2, varscan2
- IPO5 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1383579161, COSV55154409; called by muse, mutect2, varscan2
- JADE3 | c.2286G>C p.Q762H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.4); catalogued as COSV54466414; called by muse, mutect2, varscan2
- KATNIP | c.2908G>A p.V970I | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs374130852; called by muse, mutect2, varscan2
- KLK15 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140896741; called by muse, mutect2, varscan2
- NFKBIA | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.57); catalogued as COSV53752510; called by muse, mutect2
- NRXN1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58451445; called by muse, mutect2, varscan2
- RPE65 | c.957A>T p.E319D | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52015865; called by muse, mutect2
- SLC38A10 | c.1638_1641del p.E548Nfs*156 (on ENST00000374759 / NM_001037984.3; = p.E548Nfs*? on NM_138570.4) | Frame Shift Del (DEL) | VAF 53/235 reads (23%) | catalogued as rs777968247; called by mutect2, pindel, varscan2
- SLC7A7 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV53537073; called by muse, mutect2, varscan2
- SMCR8 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.248); catalogued as COSV58177300; called by muse, mutect2, varscan2
- TRIM72 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV59067734; called by muse, mutect2, varscan2
- USP28 | c.1357A>G p.S453G | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV50162501; called by muse, mutect2, varscan2
- WDFY3 | c.6823C>T p.R2275C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1306992677, COSV55700591; called by muse, mutect2, varscan2
- AACS | c.966C>A p.T322= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV55536586; called by muse, mutect2, varscan2
- C9orf131 | c.3039G>A p.S1013= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs777801222; called by mutect2, varscan2
- CROT | c.585G>T p.L195= | Silent (SNP) | VAF 76/377 reads (20%) | catalogued as COSV58974190; called by muse, mutect2, varscan2
- F10 | c.261C>T p.G87= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs763365831, COSV65021693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MS4A6A | c.228C>T p.T76= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100125121, COSV60618495, COSV60621857; called by muse, mutect2, varscan2
- PCDHA1 | c.1332G>A p.E444= | Silent (SNP) | VAF 80/300 reads (27%) | catalogued as COSV65374254; called by muse, mutect2, varscan2
- RP9 | c.237C>T p.H79= | Silent (SNP) | VAF 51/344 reads (15%) | catalogued as rs374773345, COSV51806869; called by muse, mutect2, varscan2
- TPSD1 | c.207C>T p.S69= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV52975556; called by muse, varscan2
- DNM1P46 | n.796T>A | RNA (SNP) | VAF 4/26 reads (15%) | catalogued as rs550514942; called by muse, varscan2
